Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABLQ, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABLQ-TTP2-B (Primary Tumor).

[page 1 of 2]
Previous exams

Previous exams exist.

Clinical Data and Diagnostic Questions

Pulmonary right neoformation

ICD - 0 - 3

adenocarcinoma, NOS 8140/3

Site: (R) lung, upper lobe C34.1

Material description

1. Bronchus at level section
2. Lymph node n. 4
3. Lymph node n.4
4. Lymph node n.10
5. Lymph node n.11
6. Upper lobe, right lung
7. Lymph node n.11
8. Lymph node n.7

ICD - 10

C34.11

hw
3/12/16

CDDP-YP-ABLQ-01-PR

Macro description

1. Bronchial fragment of 0.8 cm

See

The sample has been included and examined entirely

2. Two tiny anthracotic fragments.

The sample has been included and examined entirely

3. Multiples anthracotic fragments for a total volume of 2 cc

The sample has been included and examined entirely

4. Multiples anthracotic fragments, biggest of 1 cm

The sample has been included and examined entirely

5. Multiples anthracotic fragments for a total volume of 2 cc

The sample has been included and examined entirely

6. Pulmonary lobe of 13 x 10 x 3 cm, stopped by metal clips along the surgical margin that, when you cut, show greyish-blackish nodule, of solid compactness, polycyclic margins, major axis of 3 cm. This lesion comes close to the visceral pleura, without macroscopic evidence of infiltration of the same.

The remaining parenchyma is with scattered areas of markedly edematous aspect..

At the lobar hilum we close off 4 anthracotic lymph nodes, largest of 0.7 cm.

A1-A3: neoplasm + pleura

A4: random parenchyma

A5: lymph nodes of the hilum

7. Fragment of anthracotic tissue of 1 cm

The sample has been included and examined entirely

8. Three fragments of anthracotic tissue, largest of 0.7

cm The sample has been included and examined entirely

[page 2 of 2]
Micro description

1. Confirming what verbally expressed, during the extemporaneous examination, the histological definitive sections after fixation and inclusion show bronchus of section negative for neoplasm. 2.3.4.5.8. The lymph nodes n. 4, n. 10, n.11, n.7 are anthracotic and show marked histiocytosis of sinuses with microgranulomatous pattern, too.
6. It's an adenocarcinoma with a variable degree of differentiation. The neoplasm shows well differentiated areas next to other moderately poorly differentiated, the neoplasm infiltrates the pulmonary parenchyma and the above visceral pleura. There are multiple images of vascular intratumoral invasions. There are neoplastic nests in the surrounding pulmonary parenchyma, too. The neoplasm is immersed in a context of abundant scary, sclera-elastotic and anthracotic stroma. The pulmonary non-neoplastic parenchyma show bullous emphysema mainly subpleural
Bronchus of section negative for neoplasm.
Surgical margin free
7. The lymph node n. 11 is place of metastasis of poorly differentiated adenocarcinoma with the morphological characters as described under 6.

Conclusions and histopathological diagnosis

1. Bronchus of section negative of neoplasm
- 2.3.4.5.8. Lymph node anthracosis. No evidence of metastatic lesions
6. Adenocarcinoma infiltrating the pulmonary parenchyma and the visceral pleura. Intratumoural vascular invasions.
7. Lymph node metastasis of poorly differentiated adenocarcinoma.

Staging pTNM: MISSING

Primary Malignancy History		

Source: NCI Genomic Data Commons file a6a128f6-8118-4409-a520-d361a25416e7 (CDDP-ABLQ-TTP2.DC71493E-05F7-4816-8AC6-C878EBDBC112.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).